Surgical pathology report (de-identified scan), TCGA case TCGA-SC-A6LN, project TCGA-MESO (Mesothelioma), tissue source site Memorial Sloan Kettering, specimen TCGA-SC-A6LN-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: M) Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]

Clinical Diagnosis & History:
Mesothelioma, right side, former smoker.

Specimens Submitted:

- 1: Right pleural biopsy (fs)
- 2: Level seven lymph nodes (fs)
- 3: Right internal mammary lymph node (fs)
- 4: Level four lymph nodes (fs)
- 5: Portion of the right sixth rib
- 6: Right pleura
- 7: Right level ten lymph nodes

DIAGNOSIS:

1. Pleura, right, biopsy (fs):
- Malignant mesothelioma, biphasic type
2. Lymph nodes, level seven, resection (fs):
- Metastatic mesothelioma forming microscopic metastasis to four out of twelve lymph nodes (4/12)
3. Lymph node, right internal mammary, resection (fs):
- Metastatic mesothelioma forming microscopic metastasis to one lymph node (1/1), not seen in the frozen section slide
4. Lymph nodes, level four, resection (fs):
- Fourteen benign lymph nodes (0/14), two of the lymph nodes show necrosis
5. Rib, right sixth, resection:
- Fragments of bone with normo-cellular bone marrow elements
6. Pleura, right, resection:
- Malignant mesothelioma, biphasic type, see note
- No asbestos bodies seen in a minute amount of lung parenchyma
7. Lymph nodes, right level ten, resection:
- One benign lymph node (0/1)

Note: Immunostains reveal that the tumor cells are positive for AE1/AE3, calretinin and WT1, while negative for TTF1 CEA (p), and CD15. The findings

** Continued on next page **

C&F

ICD-O-3

Mesothelioma, diffuse, malignant
biphasic NOS 9053/3
path

Mesothelioma, malignant biphasic NOS
9053/3

Site (R) Pleura NOS C38.4

7/5/13

[page 2 of 5]
are consistent with the above diagnosis.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the
~~They have not been cleared or approved by the US Food and Drug~~
Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	FFITB	
	GMS	
	GMS	

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "Right pleural biopsy" and consists of an irregular fragment of red-opaque, rubbery tissue that measures 2.2 x 1.8 x 0.4 cm. The specimen is sectioned revealing a white and opaque, homogenous cut surface. Representative sections are submitted for frozen section and TFS, where the remaining specimen is submitted in its entirety in one block for permanent sections.

Summary of sections:

FSC -- frozen section control
r remaining specimen

2. The specimen is received fresh for frozen section consultation, labeled "Level seven lymph nodes" and consists of multiple fragments of red-black, rubbery lymph node candidates that measure 4 x 2 x 0.5 cm in aggregate. The lymph node candidates are submitted in their entirety for frozen section examination in two blocks; the remaining tissue is submitted in a separate block for permanent sections.

Summary of sections:

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
FSC -- frozen section control
r remaining specimen

3. The specimen is received fresh for frozen section consultation, labeled "Right internal mammary lymph node" and consists of an irregular fragment of red-black, rubbery tissue that measures 1.8 x 0.6 x 0.2 cm. The entire tissue is submitted for frozen section examination.

Summary of sections:
FSC -- frozen section control
r remaining specimen

4. The specimen is received fresh for frozen section consultation, labeled "Level four lymph nodes" and consists of multiple fragments of red-black, rubbery lymph node candidates that measure 5.5 x 3 x 0.6 cm in aggregate. The lymph node candidates are submitted in their entirety for frozen section examination in two blocks; the remaining tissue is submitted in a separate block for permanent sections.

Summary of sections:
FSC -- frozen section control
r remaining specimen

5) The specimen is received fresh, labeled "Portion of the right sixth rib" and consists of two segments of rib measuring 8.3 cm in length by 1.8 cm wide, and 13.5 cm in length by 1.7 cm light cm. Red, tan soft tissue is attached. The specimen is bisected to reveal a homogenous red tan granular and bony cut surface. The cortical surface appears intact, and no discrete lesions are noted. Representative sections are submitted for decalcification.

Summary of sections:
U -- undesignated

6) The specimen is received fresh, labeled "Right pleura", and consists of a 16.0 x 8.0 x 3.7 cm aggregate of multiple irregular portions of pink-white shaggy thickened focally hemorrhagic rubbery fibromembranous tissue. A representative section is submitted.

Summary of sections:
U undesignated
ADD-additional sections

** Continued on next page **

[page 4 of 5]
7) The specimen is received in formalin, labeled "Right level 10 lymph node" and consists of a gray purple rubbery node measuring 1.0 x 0.5 x 0.4 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

Summary of Sections:

Part 1: Right pleural biopsy (fs)

Block	Sect.	Site	PCs
1		fsc	1
1		r	1

Part 2: Level seven lymph nodes (fs)

Block	Sect.	Site	PCs
1		fsca	1
1		fsch	1

Part 3: Right internal mammary lymph node (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 4: Level four lymph nodes (fs)

Block	Sect.	Site	PCs
1		fsca	1
1		fsch	1

Part 5: Portion of the right sixth rib

Block	Sect.	Site	PCs
1		U	3

Part 6: Right pleura

Block	Sect.	Site	PCs
9		ADD	9
1		U	2

Part 7: Right level ten lymph nodes

Block	Sect.	Site	PCs
-------	-------	------	-----

** Continued on next page **

[page 5 of 5]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Malignant epithelial tumor
PERMANENT DIAGNOSIS: same
2. FROZEN SECTION DIAGNOSIS: Benign lymph nodes
PERMANENT DIAGNOSIS: see final
3. FROZEN SECTION DIAGNOSIS: Benign lymph node
PERMANENT DIAGNOSIS: see final
4. FROZEN SECTION DIAGNOSIS: One lymph node with necrosis
PERMANENT DIAGNOSIS: same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Malignant epithelial tumor
PERMANENT DIAGNOSIS: same
2. FROZEN SECTION DIAGNOSIS: Benign lymph nodes
PERMANENT DIAGNOSIS: see final
3. FROZEN SECTION DIAGNOSIS: Benign lymph node
PERMANENT DIAGNOSIS: see final
4. FROZEN SECTION DIAGNOSIS: One lymph node with necrosis
PERMANENT DIAGNOSIS: same

** End of Report **

Source: NCI Genomic Data Commons file 52830cd2-cfcf-4343-b31e-df77f8e2b2de (TCGA-SC-A6LN.579769F3-E1A6-4ACA-9217-B83152A63958.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).